Somatic mutation profile of tumor specimen MP2PRT-PAUHKL-TMP1-A (aliquot MP2PRT-PAUHKL-TMP1-A-1-0-D-A818-36) from MP2PRT case MP2PRT-PAUHKL, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.0 years (1,839 days).
Specimen MP2PRT-PAUHKL-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e71327fb-09f2-4cf4-91b0-75eeca196bf4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUHKL-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUHKL-NB1-A-1-0-D-A818-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a3737563-a41f-4636-9f46-20bb515618f1

The open-access MAF lists 21 somatic variants for this specimen: 19 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 18, Silent 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADCY8 | c.1210C>T p.R404W | Missense Mutation (SNP) | VAF 119/260 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.48); catalogued as COSV53903311; called by muse, mutect2, varscan2
- GRID1 | c.844C>T p.R282W | Missense Mutation (SNP) | VAF 32/442 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1422356227, COSV60012681; called by muse, mutect2
- KLHL36 | c.355G>A p.V119I | Missense Mutation (SNP) | VAF 201/478 reads (42%) | SIFT tolerated (0.47); PolyPhen benign (0.015); catalogued as rs200588929, COSV50718124; called by muse, mutect2, varscan2
- MYO18A | c.890G>A p.R297Q | Missense Mutation (SNP) | VAF 140/400 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs777618687; called by muse, mutect2, varscan2
- PANK4 | c.1658G>A p.R553Q | Missense Mutation (SNP) | VAF 210/555 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.663); catalogued as rs1209627355; called by muse, mutect2, varscan2
- PCDHA11 | c.2225G>A p.R742H | Missense Mutation (SNP) | VAF 166/725 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as rs374687707, COSV56514685; called by muse, mutect2, varscan2
- PCDHB8 | c.1619C>T p.P540L | Missense Mutation (SNP) | VAF 64/2688 reads (2%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs782031855, COSV50788123, COSV99177493; called by muse, mutect2
- TECTB | c.626C>T p.S209L | Missense Mutation (SNP) | VAF 16/358 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.593); catalogued as rs1004125101, COSV65594818, COSV65595613; called by muse, mutect2
- UNC80 | c.5663C>T p.T1888M | Missense Mutation (SNP) | VAF 102/266 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.524); catalogued as rs940559299; called by muse, mutect2, varscan2
- ADH1A | c.394A>T p.T132S | Missense Mutation (SNP) | VAF 78/190 reads (41%) | SIFT tolerated (0.17); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- ANGPT1 | c.795C>G p.C265W | Missense Mutation (SNP) | VAF 81/208 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.662); called by muse, mutect2, varscan2
- CDH9 | c.2001A>T p.E667D | Missense Mutation (SNP) | VAF 20/644 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- CERS2 | c.431T>C p.L144P | Missense Mutation (SNP) | VAF 41/242 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- CREBBP | c.5409_5417delinsCCGGG p.Q1803Hfs*69 | Frame Shift Del (DEL) | VAF 174/461 reads (38%) | called by pindel, varscan2*
- GPC1 | c.1424A>G p.D475G | Missense Mutation (SNP) | VAF 142/315 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MMP16 | c.25G>C p.G9R | Missense Mutation (SNP) | VAF 33/239 reads (14%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); called by muse, mutect2, varscan2
- TTN | c.78349T>G p.F26117V (on ENST00000591111; = p.F18693V on NM_003319.4) | Missense Mutation (SNP) | VAF 102/301 reads (34%) | PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- USH2A | c.11839T>A p.S3947T | Missense Mutation (SNP) | VAF 162/417 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.417); called by muse, mutect2, varscan2
- ZFHX4 | c.7165A>G p.T2389A | Missense Mutation (SNP) | VAF 149/377 reads (40%) | SIFT tolerated (0.16); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- ATG9B | c.372G>A p.P124= | Silent (SNP) | VAF 142/198 reads (72%) | catalogued as rs368831068; called by muse, varscan2
- CDH12 | c.1944C>T p.T648= | Silent (SNP) | VAF 58/558 reads (10%) | catalogued as COSV66415530; called by muse, mutect2
